Gene-level copy-number profile of tumor specimen TCGA-KK-A8I5-01A from TCGA case TCGA-KK-A8I5, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.7 years (20,337 days).
Specimen TCGA-KK-A8I5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.0b6b57a6-7bee-4162-84de-5d810744acdf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A8I5-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d461d834-6a13-4c6a-bafb-cedf5cff2483

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 514; copy number 1: 7,984; copy number 2: 51,310; copy number 3: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A8I5-01A-11D-A363-01): tumor purity 0.85, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 514 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:105,293,664–106,453,449, 20 genes: RN7SL89P, PPA2, RNU6-553P, EEF1A1P9, PIMREGP2, ATP5F1EP1, AC004066.1, ARHGEF38, ARHGEF38-IT1, AC105391.1, INTS12, GSTCD, GSTCD-AS1, NPNT, AC109361.2, AC109361.1, TBCK, AIMP1, GIMD1, LINC02173.
- chr4:112,068,010–112,636,995, 17 genes (within-gene range 0–1): CCDC34P1, TUBB8P3, AC093663.1, FAM241A, AC093663.2, AC109347.1, AP1AR, AC109347.2, TIFA, ALPK1, RTEL1P1, TOX4P1, NEUROG2, NEUROG2-AS1, RPL23AP94, ZGRF1, H3P14.
- chr4:112,973,272–113,106,955, 3 genes (within-gene range 0–1): ANK2-AS1, AC093879.1, MIR1243.
- chr4:121,824,329–122,087,811, 5 genes (within-gene range 0–2): BBS7, AC079341.1, TRPC3, AC097533.1, RN7SL335P.
- chr8:8,228,595–9,782,346, 37 genes (within-gene range 0–1): FAM86B3P, ALG1L13P, PRAG1, AC103957.1, AC103957.2, AC114550.2, AC114550.3, AC114550.1, RN7SL178P, AC087269.3, CLDN23, AC087269.2, AC087269.1, MFHAS1, RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3, TNKS, AC103834.1.
- chr8:12,628,476–30,083,208, 330 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:81,488,308–83,069,143, 26 genes: AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12, RASEF, AL499602.1.
- chr9:87,525,302–87,554,459, 2 genes: AL161787.1, DAPK1-IT1.
- chr11:113,974,881–115,128,373, 19 genes: HTR3A, ZBTB16, AP002755.1, AP002518.2, NNMT, AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2, NXPE2P1, AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2, NXPE2, AP003179.1.
- chr12:11,649,674–13,004,830, 40 genes: ETV6, BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1, DDX47, AC007215.1, AC007688.2, RPL13AP20, GPRC5A, MIR614, GPRC5D-AS1, GPRC5D, AC007688.3, AC007688.1, HEBP1, HTR7P1.
- chr14:67,819,779–68,796,253, 15 genes (within-gene range 0–1): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,598. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
